Somatic mutation profile of cancer-model specimen HCM-WCMC-0751-C54-85A (3D Organoid, passage 12; aliquot HCM-WCMC-0751-C54-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-WCMC-0751-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, secretory variant; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage IA; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 54.6 years (19,958 days).
Specimen HCM-WCMC-0751-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Cryopreserved; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 933917af-37be-4225-a292-0f535921d561.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0751-C54-10A (Blood Derived Normal), aliquot HCM-WCMC-0751-C54-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2802df3f-1a87-4a57-be2a-173ff09fce02

The open-access MAF lists 10,092 somatic variants for this specimen: 7,138 protein-altering or splice-affecting, 2,629 silent, 325 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6,402, Silent 2,629, Nonsense Mutation 433, Intron 207, Frame Shift Del 118, Splice Region 62, Splice Site 52, Frame Shift Ins 50, 3'UTR 34, 3'Flank 25, RNA 21, 5'UTR 20.

Variants (750 of 10,092; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5164C>T p.R1722* | Nonsense Mutation (SNP) | VAF 88/290 reads (30%) | hotspot (GDC flag); catalogued as rs1485978447, COSV61371609; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 209/361 reads (58%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 240/471 reads (51%) | catalogued as rs749036865, CM080076, COSV53731268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD8 | c.4414C>T p.R1472* (on ENST00000646647 / NM_001170629.2; = p.R1193* on NM_020920.4) | Nonsense Mutation (SNP) | VAF 262/471 reads (56%) | catalogued as rs991738444, COSV63219638; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CIC | c.604C>T p.R202W | Missense Mutation (SNP) | VAF 210/424 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1344635105, COSV50573658; called by muse, varscan2
- DEPDC5 | c.2293C>T p.R765* (on ENST00000400246; = p.R834* on NM_014662.5) | Nonsense Mutation (SNP) | VAF 104/238 reads (44%) | catalogued as rs541024038, CM134019, COSV56692805; ClinVar: pathogenic; called by muse, varscan2
- EIF2B3 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 167/238 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs141988913, CM124945; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F9 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 129/319 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs137852228, CM940432, CM950426; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FGF8 | c.346C>T p.R116* (on ENST00000344255 / NM_033164.4; = p.R98* on NM_006119.6) | Nonsense Mutation (SNP) | VAF 179/381 reads (47%) | catalogued as rs137852663, CM082676, CM104200, COSV60143465; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FOXP2 | c.1426C>T p.R476* | Nonsense Mutation (SNP) | VAF 75/245 reads (31%) | catalogued as rs1178491246, COSV63493477; ClinVar: pathogenic; called by muse, mutect2, varscan2
- G6PD | c.1153T>C p.C385R | Missense Mutation (SNP) | VAF 368/758 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.656); catalogued as rs137852322, CM930277; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GJA1 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 148/262 reads (56%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.768); catalogued as rs2227885, CM014191; ClinVar: likely benign / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- GLDC | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 46/361 reads (13%) | catalogued as rs386833517, CM061029, COSV58675961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 252/498 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ITPR1 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 63/203 reads (31%) | catalogued as rs886058579, COSV56974596; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNQ3 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 428/654 reads (65%) | catalogued as rs796052675, COSV66479891; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1447G>T p.E483* | Nonsense Mutation (SNP) | VAF 126/311 reads (41%) | catalogued as rs63749947, CD076834, CM076317, COSV51875855, COSV51883753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEB | c.1470+1G>A p.X490_splice | Splice Site (SNP) | VAF 99/195 reads (51%) | catalogued as rs1220787593, COSV50805874, COSV99419499; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 158/337 reads (47%) | catalogued as rs137854560, CM971046, COSV62191433, COSV62213078; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPHS2 | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 247/455 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780761368, CM021650, COSV62635857; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- OTOGL | c.3760del p.Y1254Ifs*3 (on ENST00000547103; = p.Y1245Ifs*3 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 137/324 reads (42%) | catalogued as rs1064795124; ClinVar: likely pathogenic; called by pindel, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 66/152 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 257/495 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1381C>T p.R461* (on ENST00000521381 / NM_181523.3; = p.R191* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 62/143 reads (43%) | catalogued as rs1057519838, COSV57125001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.1261C>T p.R421* | Nonsense Mutation (SNP) | VAF 138/357 reads (39%) | catalogued as rs587778617, CM164326, COSV56224693, COSV99764517; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- POGZ | c.1522C>T p.R508* | Nonsense Mutation (SNP) | VAF 134/332 reads (40%) | catalogued as rs1557901051, COSV55035225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 184/468 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205227, CM153572, COSV59042121; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- QDPR | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 159/359 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1407920390, CM155924, CM155929; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RTKN2 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 84/224 reads (38%) | hotspot (GDC flag); catalogued as rs772033296, COSV65679700, COSV65679972; called by muse, varscan2
- SCN1A | c.4943G>A p.R1648H (on ENST00000303395 / NM_001202435.3; = p.R1637H on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 185/380 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918622, CM000570; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- SCNN1B | c.880G>A p.G294S | Missense Mutation (SNP) | VAF 139/344 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs72654338, CM056056; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- SLC4A11 | c.2605C>T p.R869C | Missense Mutation (SNP) | VAF 140/276 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs121909391, CM063147; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC5A1 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 141/292 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774651252, COSV56683792; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SLCO2A1 | c.940+1G>A p.X314_splice | Splice Site (SNP) | VAF 136/278 reads (49%) | catalogued as rs765249238, CS120195; ClinVar: pathogenic; called by muse, varscan2
- SUCLA2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 125/464 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as rs370898100, COSV66222419; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TBL1XR1 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 193/455 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs878854402, CM164586, COSV70500760; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 161/344 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTPA | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 254/454 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs397515524, CM981966; ClinVar: pathogenic; called by muse, varscan2
- UBE3A | c.2314G>T p.E772* | Nonsense Mutation (SNP) | VAF 156/228 reads (68%) | catalogued as rs587781220, CD1412864, CM1412833; ClinVar: pathogenic; called by mutect2, varscan2
- USH2A | c.14453C>T p.P4818L | Missense Mutation (SNP) | VAF 272/435 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs143344549, CM065509, COSV104408063; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1535C>T p.T512M (on ENST00000373993 / NM_138932.2; = p.T504M on NM_014576.4) | Missense Mutation (SNP) | VAF 180/366 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1167572371; called by muse, varscan2
- A2ML1 | c.3431del p.F1144Sfs*17 | Frame Shift Del (DEL) | VAF 136/374 reads (36%) | catalogued as rs776004500; called by mutect2, pindel, varscan2
- A4GALT | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 205/462 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs780487343, COSV99966719; called by muse, mutect2, varscan2
- AACS | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 71/211 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022690870; called by muse, mutect2, varscan2
- AARS2 | c.2032C>T p.R678W | Missense Mutation (SNP) | VAF 125/396 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs751523537, COSV99771632; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AARS2 | c.1493C>T p.A498V | Missense Mutation (SNP) | VAF 127/388 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as rs747514149, COSV55113269; called by muse, mutect2, varscan2
- AATK | c.1828C>T p.P610S (on ENST00000326724 / NM_001080395.3; = p.P507S on NM_004920.2) | Missense Mutation (SNP) | VAF 380/772 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as rs748500719; called by muse, mutect2, varscan2
- ABCA1 | c.3583C>T p.R1195W | Missense Mutation (SNP) | VAF 154/304 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs375234343; called by muse, varscan2
- ABCA1 | c.380A>G p.K127R | Missense Mutation (SNP) | VAF 246/510 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs1394881972, COSV66058337; called by muse, mutect2, varscan2
- ABCA2 | c.6202C>T p.R2068W (on ENST00000614293; = p.R2038W on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 195/434 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775791084, COSV55808029; called by muse, mutect2, varscan2
- ABCA4 | c.1937C>T p.S646F | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs548888187, COSV64672582; called by muse, mutect2, varscan2
- ABCA4 | c.1172A>C p.K391T | Missense Mutation (SNP) | VAF 213/339 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV64673389; called by muse, mutect2, varscan2
- ABCA6 | c.3669G>T p.K1223N | Missense Mutation (SNP) | VAF 163/315 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV52641658; called by muse, mutect2, varscan2
- ABCA6 | c.1733G>A p.S578N | Missense Mutation (SNP) | VAF 138/278 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as rs752397455; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 38/137 reads (28%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA7 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 229/448 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs139251928; called by muse, varscan2
- ABCA9 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 112/220 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV100382971; called by muse, mutect2, varscan2
- ABCA9 | c.576C>T p.I192= | Splice Region (SNP) | VAF 101/213 reads (47%) | catalogued as rs777966131, COSV100383290, COSV60627123; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 182/376 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCB6 | c.1537T>C p.S513P | Missense Mutation (SNP) | VAF 99/264 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs367776479; called by muse, mutect2, varscan2
- ABCB6 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 140/259 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs745417208; called by muse, mutect2, varscan2
- ABCC10 | c.2566C>T p.R856C (on ENST00000372530 / NM_001198934.2; = p.R828C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/394 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs781586042; called by muse, mutect2, varscan2
- ABCC10 | c.4361C>T p.A1454V (on ENST00000372530 / NM_001198934.2; = p.A1426V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/336 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); catalogued as rs777467243, COSV99767598; called by muse, mutect2, varscan2
- ABCC12 | c.1262del p.P421Hfs*16 | Frame Shift Del (DEL) | VAF 27/242 reads (11%) | catalogued as rs751253143; called by mutect2, pindel
- ABCC2 | c.305C>T p.T102I | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.529); catalogued as rs1440501893; called by muse, mutect2, varscan2
- ABCC2 | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 154/296 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs757063217; called by muse, mutect2, varscan2
- ABCC3 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 323/524 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as rs34696691; called by muse, varscan2
- ABCC5 | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 309/561 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs959445939; called by muse, mutect2, varscan2
- ABCC5 | c.1497G>A p.W499* | Nonsense Mutation (SNP) | VAF 162/355 reads (46%) | catalogued as rs781410424; called by muse, mutect2, varscan2
- ABCF2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 197/329 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as rs752398993; called by muse, mutect2, varscan2
- ABCG5 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 307/595 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756734792, COSV99575586; called by muse, mutect2, varscan2
- ABCG8 | c.1294G>A p.G432S | Missense Mutation (SNP) | VAF 180/431 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs374361804, COSV99699448; called by muse, mutect2, varscan2
- ABCG8 | c.1628G>T p.R543M | Missense Mutation (SNP) | VAF 385/715 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55395322; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 226/350 reads (65%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV99865398; called by muse, varscan2
- ABHD16B | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 365/744 reads (49%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs748469189, COSV99410822; called by muse, mutect2, varscan2
- ABHD17A | c.766G>A p.E256K (on ENST00000292577 / NM_001130111.2; = p.E307K on NM_031213.4) | Missense Mutation (SNP) | VAF 61/435 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1381584788, COSV99171191; called by muse, mutect2, varscan2
- ABI3BP | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 163/387 reads (42%) | catalogued as rs750938732, COSV52527991; called by muse, mutect2, varscan2
- ABL2 | c.2129C>T p.A710V (on ENST00000502732 / NM_007314.4; = p.A695V on NM_005158.5) | Missense Mutation (SNP) | VAF 244/594 reads (41%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as rs763258624; called by muse, mutect2, varscan2
- ABLIM1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 169/401 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.118); catalogued as rs753417432, COSV53310895; called by muse, mutect2, varscan2
- ABLIM2 | c.355G>C p.G119R | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56405305, COSV99590278; called by muse, mutect2, varscan2
- ABTB1 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 188/449 reads (42%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs375653991; called by muse, mutect2, varscan2
- ABTB2 | c.1310G>A p.R437H | Missense Mutation (SNP) | VAF 261/523 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs151258781; called by muse, mutect2, varscan2
- AC005324.2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 222/476 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs541180083; called by muse, mutect2
- AC025287.4 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.204); catalogued as rs901840454; called by muse, mutect2, varscan2
- AC068580.4 | c.1066C>T p.L356F | Missense Mutation (SNP) | VAF 146/277 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as rs775579878; called by muse, mutect2, varscan2
- AC099489.1 | c.9761G>A p.R3254H | Missense Mutation (SNP) | VAF 33/433 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.172); catalogued as rs556040972; called by muse, mutect2
- AC134980.2 | c.784T>G p.F262V | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60909460; called by muse, mutect2, varscan2
- AC136428.1 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 65/440 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101434934; called by muse, mutect2, varscan2
- AC253536.7 | c.327G>A p.R109= | Splice Region (SNP) | VAF 143/311 reads (46%) | catalogued as rs779750125, COSV53159502; called by muse, mutect2, varscan2
- ACACB | c.1279G>T p.D427Y | Missense Mutation (SNP) | VAF 140/273 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); catalogued as COSV100622832; called by muse, mutect2, varscan2
- ACADSB | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 136/284 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs745900584, COSV62551468; called by muse, varscan2
- ACAN | c.6482C>T p.A2161V | Missense Mutation (SNP) | VAF 211/297 reads (71%) | SIFT tolerated (0.17); PolyPhen benign (0.405); catalogued as rs764318576, COSV61356917; called by muse, mutect2, varscan2
- ACE | c.3135C>T p.D1045= | Splice Region (SNP) | VAF 152/286 reads (53%) | catalogued as rs200011052; called by muse, varscan2
- ACHE | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 176/416 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53819467; called by muse, mutect2, varscan2
- ACRBP | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 100/266 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV57525201; called by muse, mutect2, varscan2
- ACSF2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 147/426 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs769868081; called by muse, mutect2, varscan2
- ACSL1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 198/199 reads (99%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs762658676, COSV55663671; called by muse, mutect2
- ACSL3 | c.1381C>T p.R461* | Nonsense Mutation (SNP) | VAF 178/362 reads (49%) | catalogued as rs755492618; called by muse, mutect2, varscan2
- ACSL6 | c.1148C>T p.T383I (on ENST00000379240; = p.T408I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 174/352 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.698); catalogued as rs753644715; called by muse, mutect2, varscan2
- ACSL6 | c.1103G>A p.R368Q (on ENST00000379240; = p.R393Q on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 138/288 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as rs771229984, COSV57305910, COSV99733013; called by muse, mutect2, varscan2
- ACSM1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 102/187 reads (55%) | catalogued as rs143258524, COSV99532805; called by muse, mutect2, varscan2
- ACSM1 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 195/397 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147062129; called by muse, mutect2, varscan2
- ACSM3 | c.1460G>A p.R487Q | Missense Mutation (SNP) | VAF 79/173 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs1267372126, COSV55500169, COSV55502645; called by muse, mutect2, varscan2
- ACTA1 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 196/466 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.161); catalogued as COSV64203495; called by muse, mutect2, varscan2
- ACTC1 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 129/188 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as COSV99292047; called by muse, mutect2, varscan2
- ACTL7B | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 309/552 reads (56%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as rs1216929427; called by muse, mutect2, varscan2
- ACTN2 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 120/329 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as COSV63972665; called by muse, mutect2, varscan2
- ACTN2 | c.2540C>T p.A847V | Missense Mutation (SNP) | VAF 169/433 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs370569935; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN3 | c.1379C>T p.A460V | Missense Mutation (SNP) | VAF 240/495 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1293466743, COSV100074039; called by muse, mutect2, varscan2
- ACTRT2 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 272/428 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as rs753705495; called by muse, mutect2, varscan2
- ACY3 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 200/376 reads (53%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs373268069; called by muse, mutect2, varscan2
- ADAD1 | c.32C>T p.S11L | Missense Mutation (SNP) | VAF 136/203 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs770989160, COSV56641414; called by muse, varscan2
- ADAM17 | c.1417C>T p.R473C | Missense Mutation (SNP) | VAF 259/487 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs750951308, COSV100176734; called by muse, mutect2, varscan2
- ADAM19 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 193/377 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1178207005, COSV57436288; called by muse, mutect2, varscan2
- ADAM22 | c.353G>A p.R118K | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.676); catalogued as COSV55977782; called by muse, varscan2
- ADAM8 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 294/652 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as rs1053935083, COSV69864382; called by muse, mutect2, varscan2
- ADAMTS13 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 220/461 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782601193, COSV63021363; called by muse, mutect2, varscan2
- ADAMTS15 | c.2525G>A p.R842H | Missense Mutation (SNP) | VAF 372/732 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1169596109; called by muse, mutect2, varscan2
- ADAMTS16 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 156/358 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.039); catalogued as rs745524543; called by muse, mutect2, varscan2
- ADAMTS16 | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 263/523 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1431159881, COSV57010074; called by muse, mutect2, varscan2
- ADAMTS16 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 158/364 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56978757; called by muse, mutect2, varscan2
- ADAMTS16 | c.2251C>T p.L751F | Missense Mutation (SNP) | VAF 167/327 reads (51%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.522); catalogued as COSV56990648; called by muse, mutect2, varscan2
- ADAMTS16 | c.2776G>C p.A926P | Missense Mutation (SNP) | VAF 151/294 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755948868; called by muse, mutect2, varscan2
- ADAMTS17 | c.2621C>T p.S874L | Missense Mutation (SNP) | VAF 86/296 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs377387249; called by muse, mutect2, varscan2
- ADAMTS17 | c.1957C>A p.L653M | Missense Mutation (SNP) | VAF 230/329 reads (70%) | SIFT tolerated (0.8); PolyPhen benign (0.091); catalogued as COSV51493755; called by muse, mutect2, varscan2
- ADAMTS19 | c.2350C>T p.H784Y | Missense Mutation (SNP) | VAF 190/406 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50781767; called by muse, mutect2, varscan2
- ADAMTS2 | c.3088+1G>A p.X1030_splice | Splice Site (SNP) | VAF 154/321 reads (48%) | catalogued as COSV52367932; called by muse, mutect2, varscan2
- ADAMTS2 | c.3019G>A p.D1007N | Missense Mutation (SNP) | VAF 251/493 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs761101596; called by muse, mutect2, varscan2
- ADAMTS2 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 226/474 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1207222735; called by muse, mutect2, varscan2
- ADAMTS20 | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 106/276 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.331); catalogued as COSV67141025; called by muse, mutect2, varscan2
- ADAMTS3 | c.1418del p.G473Efs*188 | Frame Shift Del (DEL) | VAF 167/467 reads (36%) | catalogued as COSV99712227; called by mutect2, pindel, varscan2
- ADAMTS7 | c.1865T>C p.V622A | Missense Mutation (SNP) | VAF 164/256 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as rs1350946573; called by muse, mutect2, varscan2
- ADAMTS9 | c.4658G>A p.R1553Q | Missense Mutation (SNP) | VAF 161/266 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs999835269, COSV55781156; called by muse, mutect2, varscan2
- ADAR | c.995C>A p.A332D | Missense Mutation (SNP) | VAF 311/511 reads (61%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.757); catalogued as COSV52720238; called by muse, mutect2, varscan2
- ADARB2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 326/622 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1293940542, COSV67216383; called by muse, varscan2
- ADCK1 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 142/303 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as rs565870217; called by muse, mutect2, varscan2
- ADCK2 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 149/383 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as rs1377539443; called by muse, mutect2, varscan2
- ADCK2 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 217/375 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as rs1460284301; called by muse, mutect2, varscan2
- ADCY10 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 94/210 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs140186304; called by muse, mutect2, varscan2
- ADCY2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 185/401 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs755729905; called by muse, mutect2, varscan2
- ADCY9 | c.3451G>A p.D1151N | Missense Mutation (SNP) | VAF 176/400 reads (44%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.982); catalogued as rs750492924; called by muse, mutect2, varscan2
- ADCY9 | c.2224T>G p.F742V | Missense Mutation (SNP) | VAF 129/260 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53574186; called by muse, mutect2, varscan2
- ADCY9 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 156/397 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV53571802; called by muse, mutect2, varscan2
- ADCYAP1 | c.358G>A p.G120S | Missense Mutation (SNP) | VAF 213/429 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs770555030; called by muse, mutect2, varscan2
- ADGB | c.4585C>T p.R1529* | Nonsense Mutation (SNP) | VAF 160/247 reads (65%) | catalogued as rs1240602803, COSV58849886; called by muse, mutect2, varscan2
- ADGRB1 | c.1469G>A p.R490H | Missense Mutation (SNP) | VAF 287/799 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60091183; called by muse, mutect2, varscan2
- ADGRD1 | c.418G>A p.G140S | Missense Mutation (SNP) | VAF 145/391 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.058); catalogued as rs374985420; called by muse, mutect2, varscan2
- ADGRE3 | c.1297G>A p.A433T | Missense Mutation (SNP) | VAF 126/264 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.269); catalogued as rs200012041; called by muse, varscan2
- ADGRE5 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 205/438 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs563311457; called by muse, mutect2, varscan2
- ADGRF1 | c.764C>T p.A255V | Missense Mutation (SNP) | VAF 104/163 reads (64%) | SIFT tolerated (0.74); PolyPhen benign (0.013); catalogued as COSV99347610; called by muse, mutect2, varscan2
- ADGRF5 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 99/274 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs146789315; called by muse, mutect2, varscan2
- ADGRG2 | c.1581G>T p.E527D (on ENST00000379869 / NM_001079858.3; = p.E524D on NM_005756.4) | Missense Mutation (SNP) | VAF 150/289 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100492331; called by muse, mutect2, varscan2
- ADGRG4 | c.3061G>A p.G1021S | Missense Mutation (SNP) | VAF 368/774 reads (48%) | SIFT tolerated (0.69); PolyPhen benign (0.067); catalogued as rs1474832544; called by muse, mutect2, varscan2
- ADGRL1 | c.2550C>T p.I850= (on ENST00000340736 / NM_001008701.3; = p.I845= on NM_014921.5) | Splice Region (SNP) | VAF 136/309 reads (44%) | catalogued as rs1253232340; called by muse, mutect2, varscan2
- ADGRL2 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 109/348 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.043); catalogued as rs1027193209; called by muse, mutect2, varscan2
- ADGRL3 | c.1627G>A p.E543K (on ENST00000506720 / NM_001322402.2; = p.E475K on NM_015236.6) | Missense Mutation (SNP) | VAF 229/423 reads (54%) | SIFT tolerated (0.72); PolyPhen benign (0.03); catalogued as rs770294775; called by muse, mutect2, varscan2
- ADGRL4 | c.1726G>T p.G576* | Nonsense Mutation (SNP) | VAF 91/169 reads (54%) | catalogued as rs746917298, COSV99056127; called by muse, mutect2, varscan2
- ADGRV1 | c.11038C>T p.R3680C | Missense Mutation (SNP) | VAF 152/366 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367738566; called by muse, varscan2
- ADRB3 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 244/534 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV61461768; called by muse, varscan2
- AFDN | c.1928G>A p.R643Q | Missense Mutation (SNP) | VAF 189/293 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753394042, COSV100653086, COSV60055721; called by muse, mutect2, varscan2
- AFDN | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 220/337 reads (65%) | catalogued as COSV100653566; called by muse, mutect2, varscan2
- AFF4 | c.520T>C p.S174P | Missense Mutation (SNP) | VAF 193/409 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as rs747072238; called by muse, mutect2, varscan2
- AGAP1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 149/312 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs758678583; called by muse, mutect2, varscan2
- AGAP4 | c.1808C>T p.T603M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1434527263; called by mutect2, varscan2
- AGAP5 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 148/382 reads (39%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs751244541, COSV65070128; called by muse, mutect2, varscan2
- AGBL5 | c.1417G>A p.D473N | Missense Mutation (SNP) | VAF 41/489 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747191439, COSV59935370; called by muse, mutect2
- AGO2 | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 360/574 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1431074938; called by muse, mutect2, varscan2
- AGO2 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 479/711 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.019); catalogued as rs372742713; called by muse, mutect2, varscan2
- AGO4 | c.1566G>A p.A522= | Splice Region (SNP) | VAF 41/128 reads (32%) | catalogued as rs569995605, COSV64616808; called by muse, mutect2, varscan2
- AGPAT3 | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 215/456 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV52372572, COSV99377302; called by muse, mutect2, varscan2
- AGRN | c.1718C>T p.T573M | Missense Mutation (SNP) | VAF 286/440 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757402635, COSV65069419; called by muse, mutect2, varscan2
- AGXT2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 136/262 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs760978202, COSV51485242; called by muse, mutect2, varscan2
- AHCTF1 | c.1186C>T p.R396* (on ENST00000366508; = p.R370* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 205/569 reads (36%) | catalogued as COSV58248386; called by muse, mutect2, varscan2
- AHDC1 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 138/852 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs768575414; called by muse, mutect2, varscan2
- AHI1 | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 96/151 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1333376430; called by muse, mutect2, varscan2
- AHNAK | c.1862G>A p.G621D | Missense Mutation (SNP) | VAF 224/462 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV99948858; called by muse, mutect2, varscan2
- AHNAK2 | c.9947C>T p.P3316L | Missense Mutation (SNP) | VAF 232/521 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs185803383; called by muse, mutect2, varscan2
- AHNAK2 | c.4399G>T p.G1467* | Nonsense Mutation (SNP) | VAF 84/651 reads (13%) | catalogued as COSV60931046; called by muse, mutect2, varscan2
- AJAP1 | c.1147A>G p.T383A | Missense Mutation (SNP) | VAF 112/187 reads (60%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as rs200738408; called by muse, mutect2, varscan2
- AJM1 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 358/673 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV56032371; called by muse, mutect2, varscan2
- AK9 | c.3416G>A p.R1139H | Missense Mutation (SNP) | VAF 154/252 reads (61%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs765149808; called by muse, mutect2, varscan2
- AKAP17A | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 128/528 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV58310678; called by muse, mutect2, varscan2
- AKAP17A | c.1987C>T p.R663W | Missense Mutation (SNP) | VAF 382/825 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.245); catalogued as rs778466247; called by muse, mutect2, varscan2
- AKAP5 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 209/391 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as rs375866913, COSV100277906; called by muse, mutect2, varscan2
- AKAP6 | c.5861C>T p.S1954F | Missense Mutation (SNP) | VAF 122/324 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.44); catalogued as rs201421428, COSV99797328; called by muse, mutect2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 24/226 reads (11%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKAP9 | c.9994C>T p.R3332* (on ENST00000359028; = p.R3308* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 131/217 reads (60%) | catalogued as rs771217988, COSV62341755; called by muse, mutect2, varscan2
- AKAP9 | c.10942C>T p.R3648* (on ENST00000359028; = p.R3624* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 84/147 reads (57%) | catalogued as rs1196642937; called by muse, mutect2, varscan2
- AKIP1 | c.481T>C p.S161P | Missense Mutation (SNP) | VAF 268/601 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1455897180; called by muse, mutect2, varscan2
- AL121899.2 | c.1729G>A p.A577T | Missense Mutation (SNP) | VAF 180/362 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs199889633; called by muse, mutect2, varscan2
- AL136295.1 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 150/373 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747944183; called by muse, mutect2, varscan2
- AL136295.1 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 194/472 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs890918250, COSV55779223; called by muse, mutect2, varscan2
- AL354761.1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 150/374 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs1045043935; called by muse, mutect2, varscan2
- ALAD | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 171/351 reads (49%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as rs897105798; called by muse, mutect2, varscan2
- ALB | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 61/360 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs375860190; called by muse, mutect2, varscan2
- ALDH3B2 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 176/358 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as rs761186674; called by muse, mutect2, varscan2
- ALDH9A1 | c.1361G>A p.R454Q | Missense Mutation (SNP) | VAF 207/384 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs142168163; called by muse, mutect2, varscan2
- ALDOA | c.608G>A p.R203H (on ENST00000642816 / NM_001243177.4; = p.R149H on NM_184041.5) | Missense Mutation (SNP) | VAF 247/545 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs762685202, COSV57632641; called by muse, mutect2, varscan2
- ALG13 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 245/462 reads (53%) | catalogued as COSV52638289; called by muse, mutect2, varscan2
- ALG13 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 151/309 reads (49%) | catalogued as COSV52634896; called by muse, mutect2, varscan2
- ALOX15B | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 225/435 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs367758401; called by muse, mutect2, varscan2
- ALOX5 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 126/269 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs778720389; called by muse, mutect2, varscan2
- ALPG | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 230/524 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553481936, COSV99779352; called by muse, mutect2, varscan2
- ALPG | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.095); catalogued as rs1299668954, COSV54966652; called by mutect2, varscan2
- ALPK1 | c.1924C>T p.H642Y | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs532078134, COSV51585432, COSV51589555; called by muse, varscan2
- ALPP | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.78); PolyPhen benign (0.04); catalogued as rs1475448953; called by mutect2, varscan2
- ALS2 | c.2321A>G p.H774R | Missense Mutation (SNP) | VAF 122/242 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.243); catalogued as rs747038450; called by muse, mutect2, varscan2
- ALS2 | c.1727C>T p.A576V | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs752347979, CM160069, COSV51887482; called by muse, mutect2, varscan2
- ALX3 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 221/324 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755174727, COSV63928530; called by muse, mutect2, varscan2
- AMDHD1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 205/364 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758223660, COSV57137813; called by muse, mutect2, varscan2
- AMDHD2 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 262/470 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53552056; called by muse, mutect2, varscan2
- AMER2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 322/632 reads (51%) | SIFT tolerated (0.45); PolyPhen benign (0.267); catalogued as rs1194945444; called by muse, varscan2
- AMFR | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 154/406 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs995498781; called by muse, mutect2, varscan2
- AMIGO3 | c.989C>T p.A330V | Missense Mutation (SNP) | VAF 264/390 reads (68%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs780494082; called by muse, mutect2, varscan2
- AMN1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 108/268 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.233); catalogued as rs765159439, COSV55670682; called by muse, mutect2, varscan2
- ANAPC4 | c.796A>C p.N266H | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs765587767; called by muse, mutect2, varscan2
- ANGPT4 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 176/360 reads (49%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs774505929, COSV101124935; called by muse, mutect2, varscan2
- ANK1 | c.5485C>T p.R1829C | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as rs751690725; called by muse, varscan2
- ANK1 | c.3511C>T p.R1171C | Missense Mutation (SNP) | VAF 164/390 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs1428777679, COSV55888428; called by muse, mutect2, varscan2
- ANK2 | c.11134G>A p.V3712I | Missense Mutation (SNP) | VAF 184/269 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs146476345; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANKAR | c.86G>T p.R29I | Missense Mutation (SNP) | VAF 172/323 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs750922987, COSV55610460; called by muse, mutect2, varscan2
- ANKFN1 | c.1595G>A p.R532K | Missense Mutation (SNP) | VAF 95/231 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1164050272; called by muse, mutect2, varscan2
- ANKH | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 162/331 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs748631663, COSV52484579; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3110C>T p.S1037L | Missense Mutation (SNP) | VAF 151/344 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as rs369911254; called by muse, mutect2, varscan2
- ANKMY2 | c.139A>G p.M47V | Missense Mutation (SNP) | VAF 82/216 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1446302874; called by muse, mutect2
- ANKRD11 | c.4885G>A p.D1629N | Missense Mutation (SNP) | VAF 237/393 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs1567567025; called by muse, mutect2, varscan2
- ANKRD12 | c.3922C>T p.R1308* | Nonsense Mutation (SNP) | VAF 201/415 reads (48%) | catalogued as rs766734820, COSV50819104; called by muse, mutect2, varscan2
- ANKRD13B | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 252/517 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs749857310, COSV67473761; called by muse, mutect2, varscan2
- ANKRD18B | c.1991C>T p.T664I | Missense Mutation (SNP) | VAF 99/221 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.517); catalogued as rs1267680655; called by muse, mutect2, varscan2
- ANKRD27 | c.1087C>T p.R363W | Missense Mutation (SNP) | VAF 58/822 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs754968391, COSV60134098; called by muse, mutect2
- ANKRD33B | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 398/771 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1277406999; called by muse, mutect2, varscan2
- ANKRD34A | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 307/774 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs868984226; called by muse, varscan2
- ANKRD36B | c.2570C>T p.S857L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs1372767427; called by mutect2, varscan2
- ANKRD39 | c.190G>A p.G64S | Missense Mutation (SNP) | VAF 142/343 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs566177154; called by muse, mutect2, varscan2
- ANKRD50 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 213/329 reads (65%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs369039763; called by muse, mutect2, varscan2
- ANKRD55 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 181/397 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1206760744; called by muse, mutect2, varscan2
- ANKRD55 | c.56G>T p.R19I | Missense Mutation (SNP) | VAF 168/385 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs1260657762; called by muse, mutect2, varscan2
- ANKRD6 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 73/204 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs1211019071; called by muse, mutect2, varscan2
- ANKRD61 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 272/489 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs565117514; called by muse, mutect2, varscan2
- ANKS6 | c.1307A>G p.H436R | Missense Mutation (SNP) | VAF 187/432 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1183083643; called by muse, mutect2, varscan2
- ANO10 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 124/182 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs1322030662; called by muse, mutect2, varscan2
- ANO2 | c.1984G>A p.E662K (on ENST00000356134 / NM_001278597.3; = p.E666K on NM_001278596.3) | Missense Mutation (SNP) | VAF 185/327 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV59008703, COSV59045108; called by muse, mutect2, varscan2
- ANO3 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 94/321 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1161758979, COSV56785162; called by muse, mutect2, varscan2
- ANO4 | c.1446G>A p.M482I (on ENST00000392977 / NM_001286615.2; = p.M447I on NM_178826.4) | Missense Mutation (SNP) | VAF 213/403 reads (53%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV54612995; called by muse, mutect2, varscan2
- ANO4 | c.2369C>T p.A790V (on ENST00000392977 / NM_001286615.2; = p.A755V on NM_178826.4) | Missense Mutation (SNP) | VAF 142/360 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763712389, COSV100151981; called by muse, mutect2, varscan2
- ANO7 | c.2024G>A p.R675H (on ENST00000274979; = p.R621H on NM_001370694.2) | Missense Mutation (SNP) | VAF 178/342 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs545708893, COSV51471794, COSV51475315; called by muse, mutect2, varscan2
- ANO8 | c.2534C>T p.S845L | Missense Mutation (SNP) | VAF 172/346 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.726); catalogued as rs376028722; called by muse, mutect2, varscan2
- ANOS1 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 56/323 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs192003597; called by muse, mutect2, varscan2
- ANOS1 | c.1150C>T p.R384W | Missense Mutation (SNP) | VAF 306/566 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs761052947, COSV99390839; called by muse, varscan2
- ANPEP | c.2360C>T p.P787L | Missense Mutation (SNP) | VAF 134/204 reads (66%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs201639683, COSV55593860; called by muse, mutect2, varscan2
- ANXA6 | c.1844C>A p.A615D | Missense Mutation (SNP) | VAF 140/292 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as COSV62905823; called by muse, mutect2, varscan2
- ANXA6 | c.1508C>A p.S503Y | Missense Mutation (SNP) | VAF 115/260 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62905891; called by muse, mutect2, varscan2
- ANXA8L1 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 72/308 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs1469800713; called by muse, mutect2, varscan2
- AOC2 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 259/541 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV53200258; called by muse, mutect2, varscan2
- AOPEP | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 167/343 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747625403, COSV52922291, COSV99469022; called by muse, mutect2, varscan2
- AP3D1 | c.1423C>T p.R475W | Missense Mutation (SNP) | VAF 192/407 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1235448607; called by muse, mutect2, varscan2
- AP3S1 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 55/135 reads (41%) | catalogued as COSV57474984; called by muse, mutect2, varscan2
- AP5S1 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 283/518 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1376813086; called by muse, mutect2, varscan2
- APBA1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 235/538 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as rs1323334260; called by muse, mutect2, varscan2
- APBB1IP | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 278/507 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV63302018, COSV63303515; called by muse, varscan2
- APBB3 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 181/395 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60052998; called by muse, mutect2, varscan2
- APC | c.5758C>T p.R1920* | Nonsense Mutation (SNP) | VAF 204/435 reads (47%) | catalogued as COSV57330105; called by muse, mutect2, varscan2
- APH1A | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 281/488 reads (58%) | SIFT tolerated (0.13); PolyPhen benign (0.437); catalogued as rs781881586; called by muse, mutect2, varscan2
- APOBEC2 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 140/376 reads (37%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.618); catalogued as rs748696871, COSV55143998; called by muse, mutect2, varscan2
- APOBEC2 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 202/330 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766919482; called by muse, varscan2
- AQP1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 264/572 reads (46%) | SIFT tolerated (1); PolyPhen probably damaging (0.95); catalogued as rs898407370, COSV61266523; called by muse, varscan2
- AQP6 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 196/415 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs769879813, COSV59646179; called by muse, mutect2, varscan2
- AQR | c.289A>G p.M97V | Missense Mutation (SNP) | VAF 133/202 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs777371947; called by muse, mutect2, varscan2
- ARAP2 | c.838C>T p.R280* | Nonsense Mutation (SNP) | VAF 178/366 reads (49%) | catalogued as COSV58281921; called by muse, varscan2
- ARAP3 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 293/573 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1303755638, COSV53349453; called by muse, mutect2, varscan2
- ARC | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 388/1098 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.41); catalogued as rs1201978742; called by muse, mutect2
- ARFGAP1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 148/339 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs368286012; called by muse, mutect2, varscan2
- ARG2 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.219); catalogued as rs181582499; called by muse, mutect2, varscan2
- ARHGAP20 | c.1595T>G p.F532C | Missense Mutation (SNP) | VAF 106/241 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV99503033; called by muse, mutect2, varscan2
- ARHGAP23 | c.3052C>T p.R1018W | Missense Mutation (SNP) | VAF 143/352 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760361796; called by muse, mutect2, varscan2
- ARHGAP24 | c.2086A>G p.M696V (on ENST00000395184 / NM_001025616.3; = p.M603V on NM_031305.3) | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs759901809, COSV99982362; called by muse, mutect2, varscan2
- ARHGAP25 | c.1835G>A p.R612H (on ENST00000409202 / NM_001007231.3; = p.R604H on NM_014882.3) | Missense Mutation (SNP) | VAF 231/562 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs374053151; called by muse, mutect2, varscan2
- ARHGAP27 | c.2032C>T p.R678W (on ENST00000428638 / NM_001282290.1; = p.R337W on NM_199282.3) | Missense Mutation (SNP) | VAF 245/778 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1052385323; called by muse, mutect2, varscan2
- ARHGAP27 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 397/562 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV51818143; called by muse, mutect2, varscan2
- ARHGAP28 | c.548G>A p.R183H (on ENST00000383472 / NM_001366230.1; = p.R24H on NM_001010000.3) | Missense Mutation (SNP) | VAF 191/391 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs375800921, COSV99151416; called by muse, mutect2, varscan2
- ARHGAP30 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 238/418 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as rs753699247, COSV100920402; called by muse, mutect2, varscan2
- ARHGAP32 | c.4178C>T p.P1393L (on ENST00000310343 / NM_001378025.1; = p.P1044L on NM_014715.4) | Missense Mutation (SNP) | VAF 234/508 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as rs762708277; called by muse, mutect2, varscan2
- ARHGAP32 | c.1180G>T p.A394S (on ENST00000310343 / NM_001378025.1; = p.A45S on NM_014715.4) | Missense Mutation (SNP) | VAF 145/309 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1448316944; called by muse, mutect2, varscan2
- ARHGAP33 | c.1420C>T p.R474W | Missense Mutation (SNP) | VAF 160/332 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs780268327, COSV50139149; called by muse, varscan2
- ARHGAP35 | c.2740G>T p.E914* | Nonsense Mutation (SNP) | VAF 220/445 reads (49%) | catalogued as COSV68330154; called by muse, mutect2, varscan2
- ARHGAP4 | c.2279G>A p.R760H | Missense Mutation (SNP) | VAF 320/641 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs782240081, COSV100509669, COSV61686792; called by muse, varscan2
- ARHGAP5 | c.4445C>T p.P1482L (on ENST00000345122 / NM_001030055.2; = p.P1481L on NM_001173.3) | Missense Mutation (SNP) | VAF 177/306 reads (58%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.995); catalogued as rs563403954; called by muse, mutect2, varscan2
- ARHGEF11 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 143/377 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746467759, COSV59352836; called by muse, mutect2, varscan2
- ARHGEF11 | c.1166C>T p.S389L | Missense Mutation (SNP) | VAF 158/413 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs748426735; called by muse, mutect2, varscan2
- ARHGEF15 | c.142C>T p.R48* | Nonsense Mutation (SNP) | VAF 142/276 reads (51%) | catalogued as rs938835951, COSV100730058, COSV62725867; ClinVar: uncertain significance; called by muse, mutect2
- ARHGEF16 | c.847C>T p.R283W | Missense Mutation (SNP) | VAF 82/276 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1365953703; called by muse, mutect2, varscan2
- ARHGEF25 | c.1511G>T p.R504I | Missense Mutation (SNP) | VAF 184/479 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV99677913; called by muse, mutect2, varscan2
- ARHGEF33 | c.1987G>A p.A663T | Missense Mutation (SNP) | VAF 283/637 reads (44%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs13020030; called by muse, mutect2, varscan2
- ARHGEF5 | c.4474C>T p.R1492W | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753838118; called by muse, mutect2, varscan2
- ARHGEF7 | c.1021G>A p.E341K (on ENST00000375741 / NM_001113511.2; = p.E163K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/189 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs753457702; called by muse, mutect2, varscan2
- ARHGEF9 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 178/391 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.306); catalogued as rs782418528, COSV99491609; called by muse, mutect2, varscan2
- ARID1B | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 374/540 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1209401384; called by muse, mutect2, varscan2
- ARID4A | c.2353G>T p.E785* | Nonsense Mutation (SNP) | VAF 153/325 reads (47%) | catalogued as COSV100793918, COSV100794476; called by muse, mutect2
- ARID5B | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 141/268 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs1206856276, COSV54421577, COSV54430067; called by muse, mutect2, varscan2
- ARL3 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 175/375 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376018992; called by muse, mutect2, varscan2
- ARMC4 | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 148/364 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as COSV100537131; called by muse, mutect2, varscan2
- ARMC9 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 138/349 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs562097929, COSV63021989; called by muse, mutect2, varscan2
- ARMCX2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 350/735 reads (48%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs782307127, COSV100168205; called by muse, mutect2, varscan2
- ARPC4 | c.380A>G p.Y127C | Missense Mutation (SNP) | VAF 78/294 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.927); catalogued as rs1475096857; called by muse, mutect2, varscan2
- ARRDC1 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 189/412 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.786); catalogued as rs201795480, COSV65060234, COSV65060321; called by muse, mutect2, varscan2
- ARSD | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 335/684 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs761702823; called by muse, mutect2, varscan2
- ARSH | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 252/495 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs145391454, COSV101139759; called by muse, mutect2, varscan2
- ART1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 240/472 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.047); catalogued as rs1467007903, COSV51705482; called by muse, varscan2
- ASAP1 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 109/376 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1020022002, COSV63047603; called by muse, mutect2
- ASB2 | c.1528G>A p.D510N | Missense Mutation (SNP) | VAF 248/493 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs567814586; called by muse, mutect2, varscan2
- ASB3 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 233/430 reads (54%) | catalogued as rs1317747370; called by muse, mutect2, varscan2
- ASB7 | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 96/300 reads (32%) | catalogued as COSV60417431; called by muse, mutect2, varscan2
- ASCC2 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 148/264 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.469); catalogued as rs746294780; called by muse, varscan2
- ASCC3 | c.5020C>T p.R1674C | Missense Mutation (SNP) | VAF 80/127 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs112466876, COSV100976363; called by muse, mutect2, varscan2
- ASCC3 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs138861677, COSV100225520; called by muse, mutect2, varscan2
- ASCL1 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 276/462 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1055293109, COSV57152329, COSV99902107; called by muse, varscan2
- ASCL4 | c.346C>T p.R116C | Missense Mutation (SNP) | VAF 164/445 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1403908918, COSV60816421; called by muse, mutect2, varscan2
- ASGR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 238/475 reads (50%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.988); catalogued as rs1174966305, COSV52649110; called by muse, mutect2, varscan2
- ASGR2 | c.746G>A p.G249D | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1045575922; called by muse, mutect2, varscan2
- ASH1L | c.4546C>T p.R1516C | Missense Mutation (SNP) | VAF 35/584 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); catalogued as rs1002567758, COSV64205926; called by muse, mutect2
- ASMTL | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 330/692 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs749599167, COSV67244646; called by muse, varscan2
- ASNS | c.1219C>T p.R407* | Nonsense Mutation (SNP) | VAF 119/190 reads (63%) | catalogued as rs1140424, COSV51551491; called by muse, mutect2, varscan2
- ASNSD1 | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 141/357 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs201544132; called by muse, mutect2, varscan2
- ASPDH | c.322C>T p.R108W | Missense Mutation (SNP) | VAF 274/540 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.544); catalogued as rs1162111256; called by muse, varscan2
- ASTN1 | c.2701C>T p.R901W | Missense Mutation (SNP) | VAF 231/442 reads (52%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as rs777093050, COSV62504008; called by muse, mutect2, varscan2
- ASXL2 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 146/300 reads (49%) | catalogued as COSV55456602; called by muse, mutect2, varscan2
- ASXL3 | c.6212A>G p.Q2071R | Missense Mutation (SNP) | VAF 152/324 reads (47%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.248); catalogued as rs763285555; called by muse, varscan2
- ATAD5 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 157/326 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs373509661, COSV58971918; called by muse, mutect2, varscan2
- ATAT1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 146/442 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1401047783; called by muse, mutect2, varscan2
- ATF7 | c.1033C>T p.R345* (on ENST00000548446 / NM_001366555.2; = p.R334* on NM_006856.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 60/434 reads (14%) | catalogued as COSV60646627; called by muse, mutect2, varscan2
- ATG13 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 149/320 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs759630324, COSV56317809; called by muse, mutect2, varscan2
- ATIC | c.854A>G p.K285R | Missense Mutation (SNP) | VAF 128/323 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99377870; called by muse, mutect2, varscan2
- ATIC | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 133/259 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs1251129229; called by muse, varscan2
- ATL3 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 142/348 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776571949, COSV100219637; ClinVar: likely benign; called by muse, varscan2
- ATOH8 | c.410C>A p.P137H | Missense Mutation (SNP) | VAF 396/833 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.174); catalogued as COSV60400265; called by muse, mutect2, varscan2
- ATOH8 | c.773C>T p.P258L | Missense Mutation (SNP) | VAF 131/271 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745848990; called by muse, varscan2
- ATP10A | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 182/317 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs550258170, COSV63518869; called by muse, mutect2
- ATP10B | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 115/274 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762149091, COSV59164051; called by muse, mutect2, varscan2
- ATP10B | c.1397C>T p.T466I | Missense Mutation (SNP) | VAF 153/301 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.087); catalogued as COSV58777691; called by muse, mutect2, varscan2
- ATP10B | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 158/340 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100469189; called by muse, mutect2, varscan2
- ATP11A | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 195/380 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.342); catalogued as rs374073309; called by muse, mutect2, varscan2
- ATP13A5 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 148/315 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs746342009; called by muse, mutect2, varscan2
- ATP13A5 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 182/374 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.422); catalogued as rs776857987; called by muse, varscan2
- ATP1A3 | c.2945G>A p.R982H (on ENST00000545399 / NM_001256214.2; = p.R969H on NM_152296.5) | Missense Mutation (SNP) | VAF 175/367 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV57488563; called by muse, mutect2, varscan2
- ATP1A3 | c.933C>G p.I311M (on ENST00000545399 / NM_001256214.2; = p.I298M on NM_152296.5) | Missense Mutation (SNP) | VAF 38/547 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV57491558; called by muse, mutect2
- ATP1A4 | c.2837G>A p.R946H | Missense Mutation (SNP) | VAF 273/463 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs980110770, COSV63625778; called by muse, mutect2, varscan2
- ATP1B1 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 147/257 reads (57%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs769851426, COSV100891633; called by muse, mutect2, varscan2
- ATP1B4 | c.204G>T p.K68N | Missense Mutation (SNP) | VAF 354/688 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV54311574; called by mutect2, varscan2
- ATP2B2 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 104/293 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.468); catalogued as rs945844574, COSV59489385; called by muse, mutect2, varscan2
- ATP2B4 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 259/445 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs986432272, COSV100398125; called by muse, mutect2, varscan2
- ATP7B | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 147/338 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV54439894; called by muse, varscan2
- ATP8A1 | c.3433G>A p.V1145I | Missense Mutation (SNP) | VAF 123/271 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.142); catalogued as rs779394605, COSV52534956; called by muse, mutect2, varscan2
- ATP8A2 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 172/378 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as rs1171835963; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8A2 | c.3272C>T p.A1091V | Missense Mutation (SNP) | VAF 110/214 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.434); catalogued as rs199725711, COSV99681789; called by muse, mutect2, varscan2
- ATP8B2 | c.1570G>T p.A524S (on ENST00000672630; = p.A491S on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 176/447 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1558273840; called by muse, mutect2, varscan2
- ATP8B4 | c.1795G>A p.A599T | Missense Mutation (SNP) | VAF 165/264 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs748504233; called by muse, mutect2, varscan2
- ATXN1 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 88/318 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs374953865; called by muse, mutect2, varscan2
- ATXN2 | c.1441C>T p.R481C (on ENST00000550104; = p.R321C on NM_002973.4) | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs772885925; called by muse, mutect2, varscan2
- ATXN7 | c.1561T>G p.F521V | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs753692014, COSV55748975; called by muse, mutect2, varscan2
- AUTS2 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 232/378 reads (61%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV61385925; called by muse, varscan2
- AXDND1 | c.2629G>T p.E877* | Nonsense Mutation (SNP) | VAF 130/382 reads (34%) | catalogued as rs867059895, COSV100858411; called by muse, mutect2, varscan2
- B3GALT1 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 219/435 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59908330; called by muse, mutect2, varscan2
- B3GALT1 | c.827G>A p.G276D | Missense Mutation (SNP) | VAF 188/415 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1301195538; called by muse, mutect2, varscan2
- B3GAT2 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 166/266 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as rs372171828; called by muse, varscan2
- B3GAT3 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 253/464 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs780467028, COSV53884548; called by muse, mutect2, varscan2
- B3GNT4 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 227/517 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs374927709; called by muse, mutect2, varscan2
- B3GNT9 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 126/455 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs775701026, COSV54625378, COSV54629284; called by muse, varscan2
- B3GNTL1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 238/431 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs761380761, COSV57952281; called by muse, mutect2, varscan2
- B3GNTL1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 246/511 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as rs772675170; called by muse, mutect2, varscan2
- B4GALNT4 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 151/312 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764676542, COSV104396012; called by muse, varscan2
- B4GALT7 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 144/322 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777921880; called by muse, mutect2, varscan2
- B4GAT1 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 233/526 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV100240214; called by muse, mutect2, varscan2
- BACH2 | c.2240C>T p.A747V | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs140270440; called by muse, varscan2
- BACH2 | c.2118C>A p.F706L | Missense Mutation (SNP) | VAF 196/288 reads (68%) | SIFT tolerated (0.82); PolyPhen probably damaging (0.996); catalogued as COSV57591252; called by muse, varscan2
- BAG6 | c.2944C>T p.R982C (on ENST00000676571; = p.R935C on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/408 reads (32%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as rs1299722541; called by muse, mutect2, varscan2
- BASP1 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 262/540 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs774730169; called by muse, varscan2
- BAZ2A | c.4883G>A p.G1628D | Missense Mutation (SNP) | VAF 121/271 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as COSV51636621; called by muse, mutect2, varscan2
- BBS12 | c.2114C>T p.T705M | Missense Mutation (SNP) | VAF 97/157 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.132); catalogued as rs372102223; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAR1 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 221/416 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as rs1239773290; called by muse, mutect2, varscan2
- BCL11A | c.2122G>A p.D708N (on ENST00000335712 / NM_001365609.1; = p.D742N on NM_018014.4) | Missense Mutation (SNP) | VAF 294/608 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV59634758; called by muse, mutect2, varscan2
- BCL11B | c.659G>A p.S220N (on ENST00000357195 / NM_001282237.2; = p.S149N on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 208/394 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as COSV100595254, COSV61733498; called by muse, mutect2, varscan2
- BCL3 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 105/446 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs143644908; called by muse, mutect2, varscan2
- BCL6B | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 157/330 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs770283128, COSV53427614; called by muse, varscan2
- BCOR | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 367/735 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.079); catalogued as rs780396086, COSV60701707; called by muse, mutect2, varscan2
- BCOR | c.235C>T p.R79W | Missense Mutation (SNP) | VAF 323/653 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1462787258; called by muse, mutect2, varscan2
- BCORL1 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 282/529 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as rs199910278, COSV99501342; called by muse, mutect2, varscan2
- BCORL1 | c.5008G>A p.E1670K | Missense Mutation (SNP) | VAF 407/783 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.303); catalogued as rs1000714095, COSV54397623; called by muse, mutect2, varscan2
- BDH1 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 175/401 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs200027383; called by muse, mutect2, varscan2
- BEND3 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 196/317 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs782456273, COSV64682373; called by muse, varscan2
- BEST2 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 176/491 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.108); catalogued as COSV50378941; called by muse, mutect2, varscan2
- BFSP1 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 284/549 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs955300290; called by muse, mutect2, varscan2
- BFSP2 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 349/697 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs200874347, COSV56588428; called by muse, mutect2, varscan2
- BHMT | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 19/326 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1324180973; called by muse, mutect2
- BIRC6 | c.3722G>A p.R1241H | Missense Mutation (SNP) | VAF 242/499 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as rs747518931; called by muse, mutect2, varscan2
- BIRC6 | c.11828T>C p.I3943T | Missense Mutation (SNP) | VAF 47/475 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1387987027; called by muse, mutect2
- BIRC7 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 287/589 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200751512, COSV104371801; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 205/406 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV57282404; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3692G>A p.R1231H | Missense Mutation (SNP) | VAF 124/301 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63243874; called by muse, mutect2, varscan2
- BLNK | c.1114C>T p.R372W | Missense Mutation (SNP) | VAF 69/213 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782566012, COSV56414279; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BLZF1 | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 183/418 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as rs368872376; called by muse, mutect2, varscan2
- BMP1 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 192/383 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs199971581, COSV60476232; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMP3 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 287/501 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1435451372, COSV51081644; called by muse, mutect2, varscan2
- BMP4 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 562/562 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756935500, COSV55417372; called by muse, mutect2, varscan2
- BMPER | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 127/285 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs763448943, COSV99032574, COSV99778978; called by muse, mutect2, varscan2
- BMPER | c.1084G>A p.G362S | Missense Mutation (SNP) | VAF 114/334 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867589039, COSV51814530; called by muse, mutect2, varscan2
- BMPR2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 171/313 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs777927015, COSV65807366; called by muse, mutect2, varscan2
- BMS1 | c.3395C>T p.T1132M | Missense Mutation (SNP) | VAF 181/388 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.475); catalogued as rs965444457, COSV65733242; called by muse, mutect2
- BMX | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 160/301 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs987183521, COSV100564472; called by muse, mutect2, varscan2
- BNIP1 | c.610C>A p.L204I | Missense Mutation (SNP) | VAF 223/462 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV51570780; called by muse, mutect2, varscan2
- BOD1L1 | c.6754G>A p.G2252R | Missense Mutation (SNP) | VAF 238/504 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50059552; called by muse, mutect2, varscan2
- BOD1L1 | c.2366G>A p.R789Q | Missense Mutation (SNP) | VAF 127/288 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs751986426, COSV99239373; called by muse, mutect2, varscan2
- BRAF | c.823G>T p.E275* | Nonsense Mutation (SNP) | VAF 57/201 reads (28%) | catalogued as CM092082; called by muse, mutect2, varscan2
- BRCA1 | c.2288C>A p.S763Y | Missense Mutation (SNP) | VAF 143/301 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV58799672; called by muse, mutect2, varscan2
- BRCA2 | c.6112C>T p.H2038Y | Missense Mutation (SNP) | VAF 132/297 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs587778123; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- BRD4 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 251/529 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1055405627, COSV99650630; called by muse, mutect2, varscan2
- BRD7 | c.1407del p.G470Efs*35 | Frame Shift Del (DEL) | VAF 92/271 reads (34%) | catalogued as COSV67159662; called by mutect2, pindel, varscan2
- BRINP3 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 325/574 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs373583743; called by muse, mutect2, varscan2
- BRINP3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 241/599 reads (40%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs376755713; called by muse, mutect2, varscan2
- BRIP1 | c.1035G>T p.K345N | Missense Mutation (SNP) | VAF 191/412 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV104386499; called by muse, mutect2, varscan2
- BRSK1 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 377/709 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1375075461, COSV58670131; called by muse, mutect2, varscan2
- BSN | c.9437G>A p.R3146H | Missense Mutation (SNP) | VAF 127/402 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs376914459; called by muse, varscan2
- BSN | c.9493G>A p.A3165T | Missense Mutation (SNP) | VAF 272/388 reads (70%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs748425735, COSV99607293; called by muse, varscan2
- BSN | c.11353C>A p.L3785I | Missense Mutation (SNP) | VAF 266/386 reads (69%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.063); catalogued as COSV56523031; called by muse, varscan2
- BSPH1 | c.37C>T p.R13* | Nonsense Mutation (SNP) | VAF 159/357 reads (45%) | catalogued as rs546690190, COSV100353580; called by muse, mutect2
- BST2 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 231/528 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs1285913459, COSV99392036; called by muse, mutect2, varscan2
- BSX | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 194/387 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as COSV58006623; called by muse, varscan2
- BTBD16 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 215/447 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs1320040555; called by muse, mutect2, varscan2
- BTBD17 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 383/735 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.158); catalogued as rs772580133, COSV64729399; called by muse, mutect2, varscan2
- BTBD19 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 103/364 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.443); catalogued as rs1415001553; called by muse, mutect2, varscan2
- BTBD8 | c.4277G>A p.R1426H (on ENST00000636805 / NM_001376131.1; = p.R913H on NM_015237.4) | Missense Mutation (SNP) | VAF 88/258 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs903908547; called by muse, mutect2, varscan2
- BTBD9 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 201/329 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as rs1294789560; called by muse, mutect2, varscan2
- BTN2A2 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 114/170 reads (67%) | catalogued as COSV61856513; called by muse, mutect2, varscan2
- BTN3A1 | c.682G>A p.G228S | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as rs754276670, COSV50025558; called by muse, mutect2, varscan2
- BUB1 | c.2966T>C p.F989S | Missense Mutation (SNP) | VAF 141/256 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1165775921; called by muse, mutect2, varscan2
- BUB3 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 160/324 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV64363954; called by muse, mutect2, varscan2
- C10orf105 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 284/608 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322115822; called by muse, mutect2, varscan2
- C10orf71 | c.3847G>A p.G1283R | Missense Mutation (SNP) | VAF 282/594 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1047765296, COSV60504292, COSV60514472; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 78/154 reads (51%) | catalogued as rs751388819; called by mutect2, varscan2
- C11orf42 | c.169C>T p.R57C | Missense Mutation (SNP) | VAF 226/460 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs906230437, COSV56415601; called by muse, mutect2, varscan2
- C11orf68 | c.577C>T p.R193C (on ENST00000530188; = p.R234C on NM_031450.4) | Missense Mutation (SNP) | VAF 259/546 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754012641; called by muse, mutect2, varscan2
- C14orf39 | c.1117G>T p.D373Y | Missense Mutation (SNP) | VAF 116/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100407558; called by muse, varscan2
- C15orf39 | c.2702C>T p.A901V | Missense Mutation (SNP) | VAF 203/326 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs372930854; called by muse, varscan2
- C16orf90 | c.158C>T p.P53L (on ENST00000399645 / NM_001353385.2; = p.P44L on NM_001080524.2) | Missense Mutation (SNP) | VAF 315/595 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs373862033; called by muse, mutect2, varscan2
- C16orf92 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 203/363 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as rs779179127, COSV54226197; called by muse, mutect2, varscan2
- C16orf96 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 196/413 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.316); catalogued as rs376310528; called by muse, mutect2, varscan2
- C18orf21 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1382232312; called by muse, mutect2
- C19orf47 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 199/444 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs199793069; called by muse, mutect2, varscan2
- C19orf57 | c.1900C>T p.R634C (on ENST00000586783 / NM_001345843.1; = p.R603C on NM_024323.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 201/388 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142083822; called by muse, mutect2, varscan2
- C19orf84 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 183/373 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1434768715; called by muse, mutect2, varscan2
- C1QC | c.611C>T p.S204L | Missense Mutation (SNP) | VAF 293/445 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1185500809; called by muse, mutect2, varscan2
- C1QTNF9B | c.808G>A p.G270R | Missense Mutation (SNP) | VAF 188/369 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765374311, COSV65944486; called by muse, mutect2, varscan2
- C1orf112 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 126/295 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.248); catalogued as rs769019631; called by muse, mutect2, varscan2
- C1orf43 | c.418C>T p.R140* (on ENST00000368521 / NM_001297718.2; = p.R106* on NM_015449.4) | Nonsense Mutation (SNP) | VAF 344/545 reads (63%) | catalogued as rs1445765778; called by muse, mutect2, varscan2
- C20orf203 | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 212/423 reads (50%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.3); catalogued as rs187530306, COSV100667944; called by mutect2, varscan2
- C20orf96 | c.731T>C p.L244P (on ENST00000360321 / NM_153269.3; = p.L243P on NM_080571.1) | Missense Mutation (SNP) | VAF 149/315 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751126025; called by muse, mutect2, varscan2
- C22orf15 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 34/719 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV59417818; called by muse, mutect2
- C2CD5 | c.2377G>A p.A793T | Missense Mutation (SNP) | VAF 111/274 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); catalogued as rs750393334, COSV61723353; called by muse, mutect2, varscan2
- C2CD6 | c.1009C>A p.L337M | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.797); catalogued as rs1157567343; called by muse, mutect2, varscan2
- C2orf16 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 176/439 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.708); catalogued as rs1277648447; called by muse, mutect2, varscan2
- C3orf22 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 142/347 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141368282; called by muse, mutect2, varscan2
- C4BPA | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 83/482 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs767574560; called by muse, mutect2, varscan2
- C4orf19 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 308/610 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.043); catalogued as rs984487767, COSV99448427; called by muse, mutect2, varscan2
- C4orf54 | c.1468del p.L490* | Frame Shift Del (DEL) | VAF 101/448 reads (23%) | catalogued as rs775566152; called by mutect2, pindel, varscan2
- C5AR1 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 185/421 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.046); catalogued as rs200857143; called by muse, mutect2, varscan2
- C5orf15 | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 198/381 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs778132177; called by muse, mutect2, varscan2
- C5orf38 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 290/652 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57413308; called by muse, mutect2
- C6orf132 | c.3337G>A p.G1113R | Missense Mutation (SNP) | VAF 140/380 reads (37%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs975465598; called by muse, varscan2
- C6orf163 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as rs1166359970, COSV66362021; called by muse, mutect2, varscan2
- C7 | c.2464G>A p.A822T | Missense Mutation (SNP) | VAF 171/376 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs780107037, COSV57474906; called by muse, mutect2, varscan2
- C7orf31 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 117/219 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs774680315, COSV52218656; called by muse, mutect2, varscan2
- C8A | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 112/171 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs772455324, COSV63485646; called by muse, mutect2, varscan2
- C9orf135 | c.262-1G>T p.X88_splice | Splice Site (SNP) | VAF 125/263 reads (48%) | catalogued as COSV65876248, COSV65877004; called by muse, mutect2, varscan2
- CA7 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 169/336 reads (50%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.89); catalogued as rs1436173328; called by muse, mutect2, varscan2
- CA9 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 161/355 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.225); catalogued as COSV100999838; called by muse, mutect2, varscan2
- CABIN1 | c.4072G>A p.D1358N | Missense Mutation (SNP) | VAF 200/458 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54080679; called by muse, mutect2, varscan2
- CABP2 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 178/360 reads (49%) | catalogued as rs761766884; called by muse, mutect2, varscan2
- CACNA1A | c.2896C>T p.R966C | Missense Mutation (SNP) | VAF 555/1005 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.804); catalogued as rs532842904; called by muse, mutect2, varscan2
- CACNA1B | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 139/306 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.646); catalogued as rs768660275, COSV53115105; called by muse, mutect2, varscan2
- CACNA1B | c.3439G>A p.V1147M | Missense Mutation (SNP) | VAF 166/360 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs201232658; called by muse, mutect2, varscan2
- CACNA1B | c.5770G>A p.G1924R | Missense Mutation (SNP) | VAF 139/264 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as rs768799057; called by muse, mutect2, varscan2
- CACNA1C | c.3200C>T p.A1067V | Missense Mutation (SNP) | VAF 147/275 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.4); catalogued as rs750998195; ClinVar: uncertain significance / benign; called by muse, varscan2
- CACNA1D | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs200101586, COSV55443603; called by muse, mutect2, varscan2
- CACNA1D | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 118/192 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV55452044; called by muse, mutect2, varscan2
- CACNA1D | c.2107A>G p.T703A (on ENST00000350061 / NM_001128840.3; = p.T723A on NM_000720.4) | Missense Mutation (SNP) | VAF 177/275 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs748590097; called by muse, mutect2, varscan2
- CACNA1E | c.2813G>A p.R938Q | Missense Mutation (SNP) | VAF 187/360 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs762485881, COSV100706283, COSV62382855; called by muse, mutect2, varscan2
- CACNA1E | c.4622C>T p.T1541I | Missense Mutation (SNP) | VAF 198/361 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV62402492; called by muse, mutect2, varscan2
- CACNA1E | c.4984G>A p.G1662S | Missense Mutation (SNP) | VAF 261/466 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62383764; called by muse, mutect2
- CACNA1F | c.3374C>T p.A1125V | Missense Mutation (SNP) | VAF 260/563 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557107162, COSV59904236; called by muse, mutect2, varscan2
- CACNA1G | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 358/562 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1296396766, COSV61723047; called by muse, mutect2, varscan2
- CACNA1H | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 258/582 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.94); catalogued as rs1325999341; called by muse, mutect2, varscan2
- CACNA1H | c.4195C>T p.R1399C | Missense Mutation (SNP) | VAF 168/441 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374596109; ClinVar: uncertain significance; called by muse, mutect2
- CACNA1I | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 300/604 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0.33); catalogued as rs746228837, COSV60801784; called by muse, mutect2, varscan2
- CACNA2D1 | c.3085C>T p.R1029* (on ENST00000356253 / NM_001366867.1; = p.R1017* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 73/202 reads (36%) | catalogued as rs1554327253, COSV62383661; called by muse, mutect2, varscan2
- CACNA2D1 | c.292G>A p.V98M | Missense Mutation (SNP) | VAF 127/198 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV62377507; called by muse, mutect2, varscan2
- CACNB1 | c.1619C>T p.T540M | Missense Mutation (SNP) | VAF 242/480 reads (50%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.107); catalogued as rs903773815, COSV59999293; called by muse, mutect2, varscan2
- CACNB4 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 93/210 reads (44%) | catalogued as rs529888359; called by muse, varscan2
- CACNG7 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 279/608 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as rs376228325; called by muse, mutect2, varscan2
- CACTIN | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 220/481 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs772632241; called by muse, mutect2, varscan2
- CAD | c.2524C>T p.R842C | Missense Mutation (SNP) | VAF 208/438 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as COSV99254395; called by muse, mutect2, varscan2
- CALD1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 68/177 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs142583902; called by muse, mutect2, varscan2
- CALN1 | c.649G>A p.G217S (on ENST00000329008 / NM_001017440.3; = p.G259S on NM_031468.4) | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs1296688169, COSV61129452; called by muse, mutect2, varscan2
- CALR3 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 145/301 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54168349; called by muse, varscan2
- CAMK2B | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 128/293 reads (44%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.024); catalogued as rs375397173, COSV51658712, COSV51662718; called by muse, varscan2
- CAMK2D | c.1409C>T p.S470L | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.063); catalogued as COSV56435506; called by muse, mutect2, varscan2
- CAMKK1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 140/302 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs367817211; called by muse, mutect2, varscan2
- CAMKV | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 136/230 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as rs772689036; called by muse, mutect2, varscan2
- CAMSAP3 | c.3628C>T p.R1210C | Missense Mutation (SNP) | VAF 272/548 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1354076030, COSV99351590; called by muse, mutect2, varscan2
- CAMTA2 | c.3422G>T p.R1141M | Missense Mutation (SNP) | VAF 241/469 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs748853701; called by muse, mutect2, varscan2
- CAMTA2 | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 163/340 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs1263808467; called by muse, mutect2, varscan2
- CAPN1 | c.1991C>T p.S664L | Missense Mutation (SNP) | VAF 204/411 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs375107477; called by muse, mutect2, varscan2
- CAPN12 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 41/512 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs750649524; called by muse, mutect2
- CAPN15 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 291/650 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs778499670; called by muse, mutect2, varscan2
- CAPN5 | c.1616G>A p.R539H (on ENST00000456580; = p.R499H on NM_004055.5) | Missense Mutation (SNP) | VAF 127/276 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.014); catalogued as rs140490506; called by muse, mutect2, varscan2
- CAPN7 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 155/237 reads (65%) | catalogued as rs368130672; called by muse, mutect2, varscan2
- CAPZA3 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 162/395 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs777052411, COSV56848439; called by muse, mutect2, varscan2
- CARD10 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 292/749 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1057519378, COSV52660187; ClinVar: risk factor; called by muse, mutect2, varscan2
- CARD9 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 178/382 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.078); catalogued as rs766983144; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CARM1 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 156/312 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV59001923; called by muse, mutect2, varscan2
- CARMIL1 | c.2789G>A p.R930Q | Missense Mutation (SNP) | VAF 66/275 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61517006; called by muse, mutect2, varscan2
- CARNMT1 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 162/370 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs761039862, COSV100961056; called by muse, varscan2
- CARNS1 | c.1391G>A p.G464D | Missense Mutation (SNP) | VAF 242/501 reads (48%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.762); catalogued as rs1464403155; called by muse, mutect2, varscan2
- CASC3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 156/342 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99229440; called by muse, varscan2
- CASC3 | c.968G>A p.R323H | Missense Mutation (SNP) | VAF 245/547 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); catalogued as rs764903865, COSV52866345, COSV52868738; called by muse, mutect2, varscan2
- CASKIN2 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 286/578 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1252536496; called by muse, mutect2, varscan2
- CASKIN2 | c.952G>A p.G318S | Missense Mutation (SNP) | VAF 185/379 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs769667783; called by muse, mutect2, varscan2
- CASP12 | c.626A>G p.D209G | Missense Mutation (SNP) | VAF 144/294 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1459189520; called by muse, mutect2, varscan2
- CASP14 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs1030524257; called by muse, mutect2, varscan2
- CASZ1 | c.3703G>A p.E1235K | Missense Mutation (SNP) | VAF 61/217 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs1383045811, COSV100681903; called by muse, mutect2, varscan2
- CATSPER2 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 135/251 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as rs781714778, COSV58661332; called by muse, mutect2, varscan2
- CATSPER3 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 202/423 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs148436794; called by muse, mutect2, varscan2
- CATSPERB | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.36); catalogued as rs181069450; called by muse, varscan2
- CATSPERG | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 240/458 reads (52%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs148618826; called by muse, mutect2, varscan2
- CAVIN3 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 312/577 reads (54%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.978); catalogued as rs35301211; called by muse, mutect2, varscan2
- CAVIN4 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 111/453 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.181); catalogued as rs369823650; called by muse, mutect2
- CBL | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 315/612 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as rs727504640, CM1514816, COSV50630511; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBLB | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 118/231 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51424023; called by muse, mutect2, varscan2
- CBLN2 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 183/440 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54050768; called by muse, mutect2, varscan2
- CBX2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 247/503 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as rs138748933, COSV53969203; called by muse, mutect2, varscan2
- CBY1 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 106/316 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs764853611, COSV53264387; called by muse, mutect2, varscan2
- CBY2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 153/344 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV60118177; called by muse, varscan2
- CC2D1A | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 152/314 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769364533; called by muse, mutect2, varscan2
- CC2D2A | c.3064C>T p.R1022W | Missense Mutation (SNP) | VAF 180/353 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs751865030, COSV67504683; called by muse, mutect2, varscan2
- CCDC102A | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 288/526 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs376490380; called by muse, mutect2, varscan2
- CCDC102B | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 129/264 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs145012390, COSV60151373, COSV60151822; called by muse, varscan2
- CCDC106 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 301/620 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1471899520; called by muse, mutect2, varscan2
- CCDC127 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 242/513 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs983986680, COSV57256768; called by muse, mutect2, varscan2
- CCDC141 | c.4052C>T p.A1351V | Missense Mutation (SNP) | VAF 130/302 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as rs931499698; called by muse, mutect2, varscan2
- CCDC141 | c.2333G>T p.R778I | Missense Mutation (SNP) | VAF 168/334 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs375777823, COSV55382539; called by muse, mutect2, varscan2
- CCDC141 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 158/320 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs760497057, COSV99041214; called by muse, varscan2
- CCDC151 | c.619C>T p.R207W | Missense Mutation (SNP) | VAF 126/260 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167009347, COSV62698407; called by muse, mutect2, varscan2
- CCDC166 | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 538/873 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs1554616893; called by muse, mutect2, varscan2
- CCDC168 | c.19870C>T p.R6624C | Missense Mutation (SNP) | VAF 143/317 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs1382341293, COSV104400437; called by muse, mutect2, varscan2
- CCDC168 | c.16229G>A p.R5410Q | Missense Mutation (SNP) | VAF 242/476 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs988621875, COSV59424236; called by muse, varscan2
- CCDC168 | c.6301C>G p.P2101A | Missense Mutation (SNP) | VAF 202/434 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.282); catalogued as COSV70555921; called by muse, mutect2
- CCDC168 | c.3920G>A p.G1307E | Missense Mutation (SNP) | VAF 164/378 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.563); catalogued as rs371030704; called by muse, varscan2
- CCDC168 | c.3818G>A p.C1273Y | Missense Mutation (SNP) | VAF 246/474 reads (52%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs1438914358; called by muse, varscan2
- CCDC174 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 85/287 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370223037, COSV57981483; called by muse, mutect2, varscan2
- CCDC183 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 135/274 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs763533452, COSV61035117; called by muse, mutect2, varscan2
- CCDC185 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 378/648 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as rs557959151, COSV64821620; called by muse, mutect2, varscan2
- CCDC27 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 72/259 reads (28%) | catalogued as rs762081181, COSV53900800; called by muse, mutect2, varscan2
- CCDC39 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs780264719, COSV56477777; ClinVar: uncertain significance; called by muse, varscan2
- CCDC39 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 144/319 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs766541691; called by muse, mutect2, varscan2
- CCDC42 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 225/446 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV53449012; called by muse, mutect2, varscan2
- CCDC47 | c.634C>T p.R212* | Nonsense Mutation (SNP) | VAF 161/350 reads (46%) | catalogued as COSV56722572, COSV56724128; called by muse, mutect2, varscan2
- CCDC54 | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 120/244 reads (49%) | catalogued as rs749035116, COSV53758628; called by muse, mutect2, varscan2
- CCDC73 | c.1974del p.K658Nfs*5 | Frame Shift Del (DEL) | VAF 82/226 reads (36%) | catalogued as COSV100067159; called by mutect2, pindel, varscan2
- CCDC73 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 151/330 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs894958378, COSV58795985; called by muse, mutect2, varscan2
- CCDC74B | c.1111C>T p.Q371* | Nonsense Mutation (SNP) | VAF 129/330 reads (39%) | catalogued as rs1404925152; called by muse, varscan2
- CCDC78 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 131/342 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1432121366; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC8 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 211/707 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.412); catalogued as rs77848696; called by muse, mutect2, varscan2
- CCDC85A | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 311/668 reads (47%) | SIFT tolerated, low confidence (0.5); PolyPhen probably damaging (0.981); catalogued as rs201522298, COSV68147667; called by muse, mutect2, varscan2
- CCDC85A | c.1027G>A p.A343T | Missense Mutation (SNP) | VAF 330/595 reads (55%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as rs1307895392, COSV68150559; called by muse, mutect2, varscan2
- CCDC85A | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 138/329 reads (42%) | catalogued as rs533730078, COSV68154970; called by muse, mutect2, varscan2
- CCDC88B | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 207/409 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); catalogued as rs200509973, COSV57265515; called by muse, mutect2, varscan2
- CCDC96 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 238/528 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as COSV100028051; called by muse, mutect2, varscan2
- CCKAR | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 227/512 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV55160128, COSV55164604; called by muse, mutect2, varscan2
- CCKBR | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 173/614 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs145658504; called by muse, mutect2, varscan2
- CCL2 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 156/338 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56773471; called by muse, mutect2, varscan2
- CCNQ | c.167A>G p.H56R | Missense Mutation (SNP) | VAF 269/562 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.202); catalogued as rs782646629; called by muse, mutect2, varscan2
- CCNT1 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 242/433 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV99980509; called by muse, mutect2, varscan2
- CCR10 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 362/728 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1337486958; called by muse, mutect2, varscan2
- CCR4 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 109/364 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410395535; called by muse, mutect2, varscan2
- CCSAP | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 266/469 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1558248869; called by muse, mutect2, varscan2
- CCSER1 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 124/274 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV61412608, COSV61472158; called by muse, mutect2, varscan2
- CCSER2 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 192/391 reads (49%) | catalogued as COSV104386338; called by muse, mutect2, varscan2
- CCT8L2 | c.1561G>A p.V521I | Missense Mutation (SNP) | VAF 198/426 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs773706506, COSV63461916; called by muse, mutect2, varscan2
- CD163 | c.2335G>T p.G779W | Missense Mutation (SNP) | VAF 114/451 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100776148; called by muse, mutect2, varscan2
- CD2 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 176/311 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369219837; called by muse, mutect2, varscan2
- CD22 | c.2029G>A p.V677I | Missense Mutation (SNP) | VAF 176/360 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.221); catalogued as rs769843750, COSV50049656; called by muse, varscan2
- CD226 | c.622G>A p.V208I | Missense Mutation (SNP) | VAF 212/389 reads (54%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs143019865; called by muse, mutect2, varscan2
- CD248 | c.1904C>A p.P635H | Missense Mutation (SNP) | VAF 93/467 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); catalogued as COSV60937902; called by muse, mutect2, varscan2
- CD276 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 127/395 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as rs371804365; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 132/372 reads (35%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD44 | c.68-1G>T p.X23_splice | Splice Site (SNP) | VAF 108/219 reads (49%) | catalogued as COSV53533251; called by muse, varscan2
- CD44 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 219/440 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); catalogued as rs1382326348; called by muse, varscan2
- CD46 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 156/336 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs1486782648, CM050660, COSV59734528; called by muse, mutect2, varscan2
- CD84 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 168/436 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs755614848; called by muse, mutect2, varscan2
- CDC20B | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 147/353 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1008892536, COSV57054773; called by muse, mutect2, varscan2
- CDC27 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 213/324 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50366211; called by muse, mutect2, varscan2
- CDC42BPB | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 113/221 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs750491753; called by muse, mutect2, varscan2
- CDC42EP1 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 323/825 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs1417214015, COSV50756177; called by muse, mutect2, varscan2
- CDC42EP4 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 209/414 reads (50%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs372077591, COSV59964043; called by muse, mutect2, varscan2
- CDC7 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 166/268 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351544686; called by muse, mutect2, varscan2
- CDCA7 | c.313G>A p.D105N (on ENST00000347703 / NM_145810.3; = p.D184N on NM_031942.5) | Missense Mutation (SNP) | VAF 118/256 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV60721934; called by muse, mutect2, varscan2
- CDCA7 | c.878G>A p.R293Q (on ENST00000347703 / NM_145810.3; = p.R372Q on NM_031942.5) | Missense Mutation (SNP) | VAF 189/350 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as COSV60720188; called by muse, varscan2
- CDCP2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 117/401 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs938719728; called by muse, varscan2
- CDH10 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 120/292 reads (41%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.476); catalogued as COSV100053313; called by muse, mutect2, varscan2
- CDH10 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 225/481 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs754465931, COSV52569054, COSV52590251; called by muse, mutect2, varscan2
- CDH10 | c.209C>A p.S70Y | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.813); catalogued as rs1285784667, COSV52576725; called by muse, mutect2, varscan2
- CDH15 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 80/277 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756843357; called by muse, mutect2, varscan2
- CDH16 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 175/461 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as rs748123110, COSV55335972; called by muse, mutect2, varscan2
- CDH18 | c.1995G>T p.E665D | Missense Mutation (SNP) | VAF 176/348 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56923309; called by muse, mutect2, varscan2
- CDH19 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 187/390 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.081); catalogued as rs767962039; called by muse, mutect2, varscan2
- CDH19 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 144/304 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs538411423, COSV50983698; called by muse, mutect2, varscan2
- CDH2 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 152/309 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199638301, COSV99298644; called by muse, varscan2
- CDH22 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 173/350 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV64839907; called by muse, mutect2, varscan2
- CDH23 | c.4390G>A p.A1464T | Missense Mutation (SNP) | VAF 156/351 reads (44%) | SIFT tolerated (0.52); PolyPhen benign (0.135); catalogued as rs756674688, COSV56467722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH4 | c.895G>A p.V299I | Missense Mutation (SNP) | VAF 192/412 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1131842; called by muse, mutect2, varscan2
- CDH7 | c.2084G>A p.R695Q | Missense Mutation (SNP) | VAF 186/365 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.598); catalogued as COSV59886164; called by muse, mutect2, varscan2
- CDH7 | c.2312G>A p.R771Q | Missense Mutation (SNP) | VAF 172/347 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as rs1294685037, COSV59893812; called by muse, mutect2, varscan2
- CDH8 | c.2392G>A p.E798K | Missense Mutation (SNP) | VAF 105/217 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.26); catalogued as COSV54845495, COSV54882936, COSV54888247; called by muse, mutect2, varscan2
- CDH9 | c.409C>T p.R137W | Missense Mutation (SNP) | VAF 186/475 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs138749280; called by muse, mutect2, varscan2
- CDHR4 | c.2317G>A p.G773R | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs764180294, COSV100391242; called by muse, varscan2
- CDHR4 | c.1854G>T p.E618D | Missense Mutation (SNP) | VAF 242/368 reads (66%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV69708930; called by muse, mutect2, varscan2
- CDK14 | c.1030C>T p.R344* (on ENST00000380050 / NM_001287135.2; = p.R326* on NM_012395.3) | Nonsense Mutation (SNP) | VAF 60/147 reads (41%) | catalogued as rs1441195365, COSV56033578; called by muse, mutect2, varscan2
- CDK16 | c.304C>T p.R102C | Missense Mutation (SNP) | VAF 197/424 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV52092673; called by muse, varscan2
- CDK16 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 231/491 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1310548831; called by muse, mutect2, varscan2
- CDK19 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 237/378 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); catalogued as rs1281979042; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4115G>A p.R1372Q | Missense Mutation (SNP) | VAF 179/381 reads (47%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs770032912; called by muse, mutect2, varscan2
- CDK5RAP2 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 172/373 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV62575224; called by muse, mutect2, varscan2
- CDKAL1 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 82/227 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs141464108; called by muse, mutect2, varscan2
- CDKL1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 186/334 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748477650; called by muse, mutect2, varscan2
- CDKL4 | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 125/254 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as COSV101115214; called by muse, mutect2, varscan2
- CDO1 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 188/398 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.048); catalogued as COSV51666273; called by muse, varscan2
- CDON | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 190/440 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs773419494, COSV54997108; called by muse, mutect2, varscan2
- CDON | c.1181G>A p.R394K | Missense Mutation (SNP) | VAF 152/300 reads (51%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV54994721; called by muse, mutect2, varscan2
- CDRT1 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 111/243 reads (46%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs778708716; called by muse, mutect2, varscan2
- CDRT1 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 174/410 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs373629441; called by muse, mutect2, varscan2
- CDYL2 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 180/352 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1346545104, COSV73654985; called by muse, mutect2, varscan2
- CDYL2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 132/284 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs756720865, COSV101629580, COSV73654363; called by muse, mutect2, varscan2
- CEACAM6 | c.994G>A p.G332S | Missense Mutation (SNP) | VAF 128/290 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.08); catalogued as rs143238640; called by muse, mutect2, varscan2
- CELA3A | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 153/206 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs202213007, COSV99266577; called by muse, mutect2, varscan2
- CELSR1 | c.4015C>T p.R1339W | Missense Mutation (SNP) | VAF 276/515 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99419784; called by muse, mutect2, varscan2
- CELSR1 | c.3937G>A p.E1313K | Missense Mutation (SNP) | VAF 226/473 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.362); catalogued as rs763382137, COSV53100956; called by muse, mutect2, varscan2
- CELSR2 | c.5867G>A p.R1956H | Missense Mutation (SNP) | VAF 214/321 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.271); catalogued as rs1424899620, COSV54777811; called by muse, varscan2
- CELSR3 | c.2801G>A p.R934Q | Missense Mutation (SNP) | VAF 106/376 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.149); catalogued as rs773929823, COSV50841870; called by muse, mutect2, varscan2
- CENPE | c.1442A>G p.E481G | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1415229155, COSV54392115; called by muse, varscan2
- CENPF | c.326A>G p.K109R | Missense Mutation (SNP) | VAF 133/329 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as rs762877045; called by muse, mutect2, varscan2
- CENPI | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 275/583 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747886221; called by muse, mutect2, varscan2
- CEP162 | c.1475G>T p.R492I | Missense Mutation (SNP) | VAF 123/354 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV57618830; called by muse, mutect2, varscan2
- CEP170 | c.3943G>T p.E1315* | Nonsense Mutation (SNP) | VAF 92/259 reads (36%) | catalogued as COSV100316179; called by muse, mutect2, varscan2
- CEP170 | c.555T>G p.D185E | Missense Mutation (SNP) | VAF 237/422 reads (56%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as COSV60515511; called by muse, mutect2, varscan2
- CEP192 | c.6718C>T p.R2240C | Missense Mutation (SNP) | VAF 155/369 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as COSV58070838; called by muse, mutect2, varscan2
- CEP350 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 202/499 reads (40%) | catalogued as COSV62486180; called by muse, mutect2, varscan2
- CEP44 | c.828G>A p.W276* | Nonsense Mutation (SNP) | VAF 86/246 reads (35%) | catalogued as rs1183899636; called by muse, mutect2, varscan2
- CEP85L | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 103/303 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.142); catalogued as rs371962633; called by muse, mutect2, varscan2
- CERKL | c.1028G>A p.R343H (on ENST00000339098 / NM_001030311.2; = p.R317H on NM_201548.5) | Missense Mutation (SNP) | VAF 180/370 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.266); catalogued as rs150587104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CERS1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 137/276 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1164242852, COSV55930127; called by muse, varscan2
- CERS6 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 181/345 reads (52%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as rs1241889470, COSV59829098, COSV59835837; called by muse, mutect2, varscan2
- CFAP206 | c.469A>G p.T157A | Missense Mutation (SNP) | VAF 78/153 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as rs1259450097; called by muse, mutect2
- CFAP299 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 141/293 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs866257430, COSV63880963; called by muse, mutect2, varscan2
- CFAP44 | c.1933C>A p.L645I | Missense Mutation (SNP) | VAF 142/314 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as COSV99869973; called by muse, mutect2, varscan2
- CFAP46 | c.6935C>T p.S2312F | Missense Mutation (SNP) | VAF 114/250 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs1355580109; called by muse, varscan2
- CFAP46 | c.2822G>A p.R941Q | Missense Mutation (SNP) | VAF 199/466 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1014224416; called by muse, mutect2, varscan2
- CFAP46 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 258/492 reads (52%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs767116282, COSV100886898; called by muse, mutect2, varscan2
- CFAP47 | c.9107C>T p.T3036M | Missense Mutation (SNP) | VAF 168/388 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs143613641, COSV101074069; called by muse, varscan2
- CFAP53 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 206/397 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); catalogued as COSV68351561; called by muse, mutect2, varscan2
- CFAP54 | c.7139A>G p.N2380S | Missense Mutation (SNP) | VAF 192/332 reads (58%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.801); catalogued as rs1565961695; called by muse, mutect2, varscan2
- CFAP58 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 171/355 reads (48%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs746292556, COSV57211513; called by muse, mutect2, varscan2
- CFAP65 | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 170/356 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1225440905; called by muse, mutect2, varscan2
- CHCHD7 | c.26G>T p.R9I (on ENST00000355315 / NM_001011671.3; = p.R21I on NM_024300.4) | Missense Mutation (SNP) | VAF 164/302 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100374646; called by muse, mutect2, varscan2
- CHD3 | c.1868G>A p.R623H | Missense Mutation (SNP) | VAF 175/403 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV57877772; called by muse, mutect2, varscan2
- CHD4 | c.3974G>T p.R1325I (on ENST00000357008 / NM_001363606.2; = p.R1338I on NM_001273.5) | Missense Mutation (SNP) | VAF 299/537 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58895972, COSV58909317; called by muse, mutect2, varscan2
- CHD6 | c.7480G>A p.G2494R | Missense Mutation (SNP) | VAF 138/540 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369533037, COSV64695229; called by muse, mutect2, varscan2
- CHD8 | c.907C>T p.R303W (on ENST00000646647 / NM_001170629.2; = p.R24W on NM_020920.4) | Missense Mutation (SNP) | VAF 156/386 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as rs773890331, COSV67872859; called by muse, mutect2, varscan2
- CHD9 | c.6307C>T p.R2103C | Missense Mutation (SNP) | VAF 209/431 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs530503801, COSV54611935; called by muse, mutect2, varscan2
- CHEK1 | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 132/302 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.746); catalogued as rs537858020; called by muse, mutect2, varscan2
- CHFR | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 177/430 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1048846757; called by muse, mutect2, varscan2
- CHIT1 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 238/392 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs143254493; called by muse, mutect2, varscan2
- CHL1 | c.2917C>T p.P973S (on ENST00000397491 / NM_001253387.1; = p.P989S on NM_006614.4) | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.782); catalogued as rs757399198; called by muse, mutect2, varscan2
- CHRNA1 | c.356G>A p.G119D (on ENST00000261007 / NM_001039523.3; = p.G94D on NM_000079.4) | Missense Mutation (SNP) | VAF 110/360 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV53685050; called by muse, varscan2
- CHRNA7 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 215/575 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs547741252, COSV100181814; called by muse, mutect2, varscan2
- CHRNB2 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 402/692 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749354110, COSV63808574; called by muse, mutect2, varscan2
- CHRNB4 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.191); catalogued as rs775858779, COSV55716492; called by muse, mutect2, varscan2
- CHST12 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 302/585 reads (52%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs149493991; called by muse, mutect2, varscan2
- CHST15 | c.1426C>A p.L476I | Missense Mutation (SNP) | VAF 194/429 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV100655309; called by muse, mutect2, varscan2
- CHST15 | c.1022C>T p.T341I | Missense Mutation (SNP) | VAF 118/307 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV60565886; called by muse, varscan2
- CHST4 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 216/511 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs1300121216; called by muse, mutect2, varscan2
- CHST9 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 154/295 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV52439630, COSV52441080; called by muse, mutect2, varscan2
- CHTOP | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 262/447 reads (59%) | catalogued as rs946183413, COSV64154932; called by muse, mutect2, varscan2
- CIB1 | c.519C>A p.F173L | Missense Mutation (SNP) | VAF 81/259 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100153322; called by muse, mutect2, varscan2
- CIDEA | c.329C>T p.P110L | Missense Mutation (SNP) | VAF 105/242 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs372248989, COSV100254917; called by muse, mutect2, varscan2
- CILP2 | c.1510G>A p.A504T | Missense Mutation (SNP) | VAF 287/582 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs756936052; called by muse, mutect2, varscan2
- CISH | c.754C>T p.R252* (on ENST00000348721 / NM_145071.4; = p.R269* on NM_013324.6) | Nonsense Mutation (SNP) | VAF 86/271 reads (32%) | catalogued as rs770662400, COSV100811741; called by muse, mutect2, varscan2
- CIT | c.2172G>T p.K724N | Missense Mutation (SNP) | VAF 142/281 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV99949848; called by muse, mutect2, varscan2
- CIZ1 | c.2539C>T p.R847W | Missense Mutation (SNP) | VAF 264/554 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs778076408; called by muse, varscan2
- CKAP2L | c.2027C>T p.P676L | Missense Mutation (SNP) | VAF 112/229 reads (49%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.92); catalogued as rs755625375; called by muse, mutect2, varscan2
- CKMT1A | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs527344657, COSV63256737; called by muse, mutect2, varscan2
- CLASP1 | c.3760C>T p.R1254C | Missense Mutation (SNP) | VAF 169/374 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV55330094; called by muse, mutect2, varscan2
- CLCC1 | c.518G>A p.R173Q (on ENST00000356970 / NM_001377464.1; = p.R123Q on NM_015127.5) | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs764536408; called by muse, mutect2, varscan2
- CLCN3 | c.2369G>A p.R790H | Missense Mutation (SNP) | VAF 129/171 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as rs771142045, COSV100641645; called by muse, mutect2, varscan2
- CLCN5 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 151/367 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as CM973255, COSV100259947; called by muse, mutect2, varscan2
- CLCN6 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 248/408 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV56742006; called by muse, mutect2, varscan2
- CLCNKB | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 131/239 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.667); catalogued as rs985164800; called by muse, mutect2, varscan2
- CLCNKB | c.693C>A p.F231L | Missense Mutation (SNP) | VAF 310/463 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV65159697; called by muse, mutect2, varscan2
- CLDN1 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs147881276, COSV55044256; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLDN7 | c.571A>G p.S191G | Missense Mutation (SNP) | VAF 145/296 reads (49%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100598282; called by muse, mutect2, varscan2
- CLEC16A | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 165/351 reads (47%) | catalogued as rs781624773; called by muse, mutect2, varscan2
- CLEC2L | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 93/219 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.263); catalogued as rs1021895960; called by muse, mutect2, varscan2
- CLGN | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 127/190 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1475083337; called by muse, mutect2, varscan2
- CLIC3 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 304/638 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs887795182; called by muse, mutect2, varscan2
- CLIP1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 170/338 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs749979444; called by muse, varscan2
- CLMN | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 132/243 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761123039; called by muse, varscan2
- CLMP | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 177/369 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs201115327, COSV71649276; called by muse, mutect2, varscan2
- CLN6 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.814); catalogued as rs140179213; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLPP | c.660C>T p.I220= | Splice Region (SNP) | VAF 152/301 reads (50%) | catalogued as rs116642585; called by muse, mutect2, varscan2
- CLPX | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 216/458 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs775288540, COSV100269474, COSV55644729; called by muse, mutect2, varscan2
- CLRN1 | c.365A>T p.N122I (on ENST00000327047 / NM_174878.3; = p.N46I on NM_052995.2) | Missense Mutation (SNP) | VAF 171/344 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55805191, COSV55806376; called by muse, mutect2, varscan2
- CLSTN3 | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 188/405 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1565653764; called by muse, mutect2, varscan2
- CLTC | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1371970086; called by muse, mutect2, varscan2
- CLU | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 226/466 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as rs375198703; called by muse, mutect2, varscan2
- CLUL1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369234574, COSV58113533; called by muse, mutect2, varscan2
- CMAS | c.665G>T p.R222I | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99982682; called by muse, mutect2, varscan2
- CMKLR1 | c.392C>T p.T131I (on ENST00000312143 / NM_001142344.2; = p.T129I on NM_004072.3) | Missense Mutation (SNP) | VAF 132/337 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs879355530; called by muse, mutect2, varscan2
- CMTR1 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 193/274 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100990932; called by muse, varscan2
- CMTR1 | c.944C>T p.S315F | Missense Mutation (SNP) | VAF 144/234 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); catalogued as COSV99056361; called by muse, varscan2
- CNGA3 | c.1706G>A p.R569H | Missense Mutation (SNP) | VAF 218/433 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201782746, CM014559; called by muse, mutect2, varscan2
- CNGA3 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 268/452 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs770308610, CM101949, COSV55623584; ClinVar: uncertain significance; called by muse, varscan2
- CNGA3 | c.1982G>A p.R661H | Missense Mutation (SNP) | VAF 157/362 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs144715956; ClinVar: uncertain significance; called by muse, varscan2
- CNGA4 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 216/452 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs146413631; called by muse, mutect2, varscan2
- CNNM1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 132/584 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.34); catalogued as rs1231118367; called by muse, varscan2
- CNOT4 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 95/152 reads (63%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs754797076, COSV59658797; called by muse, mutect2, varscan2
- CNPY1 | c.92G>A p.R31Q (on ENST00000636446; = p.R12Q on NM_001369813.1) | Missense Mutation (SNP) | VAF 88/215 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as rs913478493; called by muse, varscan2
- CNR1 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 188/272 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs768033952, COSV100759232, COSV62986936; called by muse, varscan2
- CNST | c.133G>A p.G45R | Missense Mutation (SNP) | VAF 384/929 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1292320355, COSV63620891, COSV63621000; called by muse, mutect2, varscan2
- CNTLN | c.3563A>G p.K1188R | Missense Mutation (SNP) | VAF 118/207 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0.399); catalogued as rs755970051; called by muse, mutect2, varscan2
- CNTN6 | c.2308C>T p.P770S | Missense Mutation (SNP) | VAF 184/282 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs1377380435, COSV100611369; called by muse, mutect2
- CNTNAP1 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 249/490 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as COSV52848813; called by muse, mutect2, varscan2
- CNTNAP1 | c.3277G>A p.A1093T | Missense Mutation (SNP) | VAF 135/461 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.301); catalogued as rs1290176252; called by muse, mutect2, varscan2
- CNTRL | c.3358C>T p.R1120* | Nonsense Mutation (SNP) | VAF 167/332 reads (50%) | catalogued as rs1564271317, COSV99441472; called by muse, mutect2, varscan2
- CNTRL | c.3820C>T p.R1274* | Nonsense Mutation (SNP) | VAF 279/600 reads (47%) | catalogued as rs1209232570; called by muse, mutect2, varscan2
- COBL | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 123/346 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs559191037; called by muse, mutect2, varscan2
- COL12A1 | c.6541G>A p.D2181N | Missense Mutation (SNP) | VAF 191/293 reads (65%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs368397177; called by muse, mutect2, varscan2
- COL12A1 | c.4196G>A p.R1399H | Missense Mutation (SNP) | VAF 184/272 reads (68%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as rs200125060; called by muse, mutect2, varscan2
- COL18A1 | c.1497C>A p.F499L (on ENST00000359759 / NM_130444.3; = p.F264L on NM_030582.4) | Missense Mutation (SNP) | VAF 344/696 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753638853, COSV62699682; called by muse, mutect2, varscan2
- COL19A1 | c.2629C>T p.R877* | Nonsense Mutation (SNP) | VAF 168/242 reads (69%) | catalogued as rs773583688, COSV59578740; called by muse, mutect2, varscan2
- COL1A1 | c.3509G>A p.R1170H | Missense Mutation (SNP) | VAF 221/704 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs993936431; called by muse, mutect2, varscan2
- COL21A1 | c.989G>A p.G330D | Missense Mutation (SNP) | VAF 70/210 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.065); catalogued as rs772631267; called by muse, mutect2, varscan2
- COL22A1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 183/569 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs749432033, COSV100281432, COSV57336933; called by muse, mutect2, varscan2
- COL24A1 | c.2648C>T p.P883L | Missense Mutation (SNP) | VAF 55/207 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as rs753030963, COSV65309470; called by muse, mutect2, varscan2
9,342 further variants in this file (6,388 protein-altering or splice-affecting, 2,629 silent, 325 other) are not listed here.
